Gene-level copy-number profile of tumor specimen TCGA-77-8150-01A from TCGA case TCGA-77-8150, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 64.3 years (23,474 days).
Specimen TCGA-77-8150-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.ab665c5d-3733-4002-a724-946c1c5265b0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-8150-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/60ab40f8-6b3f-4840-a666-f8e16b1ba876

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 70; copy number 1: 2; copy number 2: 15,401; copy number 3: 13,521; copy number 4: 12,119; copy number 5: 13,016; copy number 6: 3,092; copy number 7: 1,878; copy number 8: 134; copy number 9: 503; copy number 11: 69.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-8150-01A-11D-2243-01): tumor purity 0.56, ploidy 3.72, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,290,406–11,290,663, 1 gene: AC083855.1.
- chr5:127,517,640–132,076,170, 51 genes (within-gene range 0–2): PRRC1, AC010424.3, CTXN3, AC022118.1, CCDC192, CUL1P1, AC068658.1, LINC01184, SLC12A2, KDELC1P1, FBN2, Y_RNA, SLC27A6, AC008588.1, ISOC1, MIR4633, AC008679.1, MIR4460, ADAMTS19-AS1, ADAMTS19, AC008591.1, MINAR2, CHSY3, RNU6ATAC10P, RNA5SP191, HSPA8P4, RNU7-53P, ARL2BPP4, AC005741.1, AC006525.1, AC113367.1, AC113367.3, AC113367.2, HINT1, LYRM7, CDC42SE2, AC004777.1, RAPGEF6, AC008695.1, AC008497.1, FNIP1, ACTBP4, AC005593.1, MEIKIN, AC034228.3, AC034228.2, ACSL6, ACSL6-AS1, AC034228.1, IL3, CSF2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,584 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 7–11 (broad region; genes not listed).
- chr5:17,684,584–31,066,132, 117 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:73,593,194–106,036,432, 637 genes, copy number 8–9 (within-gene range 5–9) (broad region; genes not listed).
- chr9:30,388,935–32,676,520, 27 genes, copy number 7: LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23, RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1.
- chr15:61,181,249–61,240,331, 3 genes, copy number 7: AC012404.1, AC012404.2, AC107905.1.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
